Somatic mutation profile of tumor specimen TCGA-LN-A49X-01A (aliquot TCGA-LN-A49X-01A-31D-A27G-09) from TCGA case TCGA-LN-A49X, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 44.2 years (16,154 days).
Specimen TCGA-LN-A49X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70d2cdaa-e3ca-43cf-8ae7-7533d49107c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LN-A49X-10A (Blood Derived Normal), aliquot TCGA-LN-A49X-10A-01D-A27G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/036991df-8882-4947-9bd4-eda500180f43

The open-access MAF lists 73 somatic variants for this specimen: 53 protein-altering or splice-affecting, 16 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 16, Nonsense Mutation 6, RNA 3, Splice Site 3, Frame Shift Ins 2, Intron 1, Translation Start Site 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 121/408 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AMY1A | c.962G>T p.G321V | Missense Mutation (SNP) | VAF 23/221 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100915794; called by muse, mutect2, varscan2
- B3GAT1 | c.425C>T p.T142M | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1245779483, COSV100438071, COSV56995759; called by muse, mutect2, varscan2
- BCDIN3D | c.265C>A p.L89I | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as COSV61702822; called by muse, mutect2
- BRD9 | c.895G>A p.V299M | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); catalogued as rs753813330, COSV100057422; called by muse, mutect2, varscan2
- CABP4 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs762298430; called by muse, mutect2, varscan2
- CCNY | c.17C>G p.S6W | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99038003, COSV99591086; called by muse, mutect2
- CHD3 | c.4454G>A p.R1485H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs775142325; called by muse, mutect2, varscan2
- FLG | c.9695C>T p.S3232F | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.974); catalogued as COSV100910253; called by muse, mutect2, varscan2
- GGNBP2 | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.682); catalogued as rs752364975; called by muse, mutect2, varscan2
- H2BC9 | c.44C>G p.S15C | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.055); catalogued as COSV99769149; called by muse, mutect2, varscan2
- H3C2 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 13/100 reads (13%) | catalogued as COSV52518637, COSV52519594, COSV99451261; called by muse, mutect2, varscan2
- RECQL5 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.844); catalogued as COSV53126606; called by muse, mutect2, varscan2
- RXFP2 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs778183013, COSV53634268; called by muse, mutect2, varscan2
- ST18 | c.2203G>A p.V735M | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs369893285; called by muse, mutect2, varscan2
- TRMT13 | c.893G>T p.R298L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs779650558, COSV61582636; called by muse, mutect2
- ADAR | c.329A>G p.H110R | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALPP | c.777G>A p.W259* | Nonsense Mutation (SNP) | VAF 10/97 reads (10%) | called by muse, mutect2, varscan2
- ANKRD26 | c.3928G>T p.D1310Y | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.134); called by muse, mutect2
- ATP13A3 | c.2957A>G p.N986S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- CCDC124 | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2
- CLEC14A | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 6/53 reads (11%) | called by muse, mutect2, varscan2
- CTNNA1 | c.1085A>T p.D362V | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- DPCD | c.71G>C p.R24T | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- EP400 | c.5110-2A>G p.X1704_splice | Splice Site (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- FGF14 | c.179G>C p.R60T | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GDF11 | c.1032G>C p.Q344H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- KDM3B | c.3389A>T p.Q1130L | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- KRT14 | c.881_887del p.M294Rfs*18 | Frame Shift Del (DEL) | VAF 16/100 reads (16%) | called by mutect2, pindel, varscan2
- NOTCH2 | c.3059C>T p.S1020F | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- NOTCH3 | c.1952-1G>A p.X651_splice | Splice Site (SNP) | VAF 11/43 reads (26%) | called by muse, mutect2, varscan2
- OTOGL | c.1301A>G p.N434S (on ENST00000547103; = p.N425S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- OTULIN | c.930C>A p.Y310* | Nonsense Mutation (SNP) | VAF 31/99 reads (31%) | called by muse, mutect2, varscan2
- PCDHB15 | c.992G>T p.C331F | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); called by mutect2, varscan2
- PCDHGC5 | c.1276G>A p.A426T | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PHKG2 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- PIK3R6 | c.865T>A p.L289M | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PITPNB | c.372+1G>A p.X124_splice | Splice Site (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- RALGAPB | c.1655A>G p.N552S | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2
- RCHY1 | c.43C>T p.R15* | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2
- RPA4 | c.746A>G p.Y249C | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- SCIN | c.1565T>C p.I522T (on ENST00000297029 / NM_001112706.3; = p.I275T on NM_033128.3) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- SNED1 | c.224A>T p.N75I | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- THAP4 | c.280dup p.A94Gfs*59 | Frame Shift Ins (INS) | VAF 12/60 reads (20%) | called by mutect2, pindel, varscan2
- TMEM131 | c.3529A>G p.I1177V | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TNK2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- TRAV14DV4 | c.299C>G p.S100C | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- TTPAL | c.739A>G p.I247V | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.196); called by muse, mutect2
- USP19 | c.2918C>G p.P973R | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.403); called by mutect2, varscan2
- VPS29 | c.244A>G p.I82V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- XKR4 | c.1603_1626del p.F535_A542del | In Frame Del (DEL) | VAF 6/55 reads (11%) | called by mutect2, pindel
- ZBED4 | c.3430dup p.L1144Pfs*12 | Frame Shift Ins (INS) | VAF 10/54 reads (19%) | called by mutect2, pindel, varscan2
- ZFP64 | c.1396G>A p.D466N | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ASAP2 | c.1797C>T p.T599= | Silent (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- COG2 | c.1467A>G p.Q489= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs747018671; called by muse, mutect2, varscan2
- GALNT16 | c.1002T>C p.S334= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as rs755771930; called by muse, mutect2, varscan2
- GPR141 | c.573C>A p.A191= | Silent (SNP) | VAF 11/98 reads (11%) | called by muse, mutect2, varscan2
- IL9R | c.360C>T p.I120= | Silent (SNP) | VAF 21/82 reads (26%) | called by muse, mutect2, varscan2
- MORC4 | c.732A>G p.V244= | Silent (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2
- NUP153 | c.1353A>G p.R451= | Silent (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2, varscan2
- PCDHA3 | c.1554C>T p.Y518= | Silent (SNP) | VAF 11/203 reads (5%) | catalogued as rs957021626; called by muse, mutect2
- PLAT | c.1299G>A p.P433= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as rs188811714; called by muse, mutect2
- QSOX1 | c.2173C>T p.L725= | Silent (SNP) | VAF 12/69 reads (17%) | called by muse, mutect2, varscan2
- SCN9A | c.4974C>T p.Y1658= (on ENST00000303354; = p.Y1647= on NM_002977.3) | Silent (SNP) | VAF 12/124 reads (10%) | catalogued as rs757858235, COSV57600994; ClinVar: likely benign; called by muse, mutect2
- SLC25A25 | c.861G>T p.G287= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as rs765217256; called by muse, mutect2, varscan2
- SLC26A9 | c.648G>C p.L216= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV100536074, COSV61604804; called by muse, mutect2
- TLL2 | c.2058C>T p.P686= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs762651565; called by muse, mutect2, varscan2
- ZFYVE27 | c.586C>T p.L196= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs893637159; called by muse, mutect2, varscan2
- ZNF780A | c.1731A>G p.K577= | Silent (SNP) | VAF 6/83 reads (7%) | catalogued as rs779961382, COSV61814475, COSV61815645; called by muse, mutect2
- AC024940.1 | n.2037C>A | RNA (SNP) | VAF 12/99 reads (12%) | called by muse, mutect2, varscan2
- AC073310.1 | n.863C>T | RNA (SNP) | VAF 21/93 reads (23%) | called by muse, mutect2, varscan2
- MIR548I1 | n.72T>C | RNA (SNP) | VAF 14/208 reads (7%) | catalogued as rs770769535; called by muse, mutect2
- TTN | c.10361-4986G>A | Intron (SNP) | VAF 11/72 reads (15%) | catalogued as rs762675930; called by muse, mutect2, varscan2
